Somatic mutation profile of tumor specimen 0DYE72 from CCDI case PBCPWF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.8 years (7,230 days).
Specimen 0DYE72: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3030ada1-ffa2-4fcb-8386-8af4da0b57fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYE6E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b5ce8c1-a065-4e12-b065-c3242c961624

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PACRGL | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 177/480 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, varscan2
- FLYWCH1 | c.1866G>A p.A622= (on ENST00000253928 / NM_001308068.2; = p.A621= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/308 reads (39%) | catalogued as rs373999632; called by muse, varscan2
- CFLAR | c.524-64A>G | Intron (SNP) | VAF 73/202 reads (36%) | catalogued as rs1216101242; called by muse, varscan2
- SLC35A2 | c.426+68G>A | Intron (SNP) | VAF 111/512 reads (22%) | catalogued as rs1179638943; called by muse, varscan2
